Somatic mutation profile of tumor specimen MP2PRT-PAUKXN-TBP1-A (aliquot MP2PRT-PAUKXN-TBP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUKXN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 2.6 years (957 days).
Specimen MP2PRT-PAUKXN-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e5e7e43-eef0-4753-880d-d79265a1954d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKXN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKXN-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a24a2fa5-cb0a-41f2-a907-ac99cc8ccfb5

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRXN1 | c.3719-1416C>T | Intron (SNP) | VAF 35/230 reads (15%) | catalogued as rs1201575289, COSV60500247; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 84/660 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs775171724, COSV51852839; called by muse, mutect2, varscan2
- ACKR3 | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs777382973, COSV56023782; called by muse, mutect2
- CCDC188 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 41/535 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1052127076; called by muse, mutect2
- FREM2 | c.7294C>T p.R2432W | Missense Mutation (SNP) | VAF 57/533 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs141120365, COSV54832682; called by muse, mutect2, varscan2
- LACTBL1 | c.436C>T p.R146C (on ENST00000618559; = p.R191C on NM_001289974.2) | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1479731987, COSV70777283; called by muse, mutect2, varscan2
- TNR | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 124/646 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.225); catalogued as rs778290581, COSV54873859, COSV54893016; called by muse, mutect2, varscan2
- UNC13A | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53196822; called by muse, mutect2
- FRYL | c.254A>G p.Q85R | Missense Mutation (SNP) | VAF 59/401 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- MCTP1 | c.1750C>A p.L584M | Missense Mutation (SNP) | VAF 19/399 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PTPRS | c.5266C>A p.P1756T | Missense Mutation (SNP) | VAF 19/483 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- AFF3 | c.3030G>A p.S1010= | Silent (SNP) | VAF 70/399 reads (18%) | catalogued as rs747852637, COSV57851113; called by muse, mutect2, varscan2
